Gene-level copy-number profile of tumor specimen C3N-02284-01 from CPTAC case C3N-02284, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.9 years (25,536 days).
Specimen C3N-02284-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9bf66870-c42f-4a5b-a791-91ce03bcb923.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02284-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/4f2578c5-8fdb-44e7-85ba-2703566afa65

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 603; copy number 1: 17,095; copy number 2: 32,571; copy number 3: 6,824; copy number 4: 1,601; copy number 5: 87; copy number 6: 39; copy number 7: 27; copy number 9: 4; copy number 10: 6; copy number 11: 2; copy number 13: 1; copy number 16: 37; copy number 17: 4; copy number 23: 5.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:104,667,749–104,669,576, 1 gene (within-gene range 0–2): EIF4BP6.
- chr9:20,999,509–25,938,434, 75 genes (broad region; genes not listed).
- chr9:29,317,833–29,318,952, 1 gene: AL353684.1.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr9:63,974,762–64,440,180, 5 genes: AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9.
- chr9:95,065,350–95,065,446, 1 gene (within-gene range 0–1): MIR6081.
- chr9:138,129,399–138,129,526, 1 gene: AL591424.1.
- chr13:47,745,736–48,037,968, 1 gene (within-gene range 0–1): SUCLA2.
- chr13:47,930,153–47,956,830, 2 genes: LINC00562, AL157369.1.
- chr18:80,140–88,570, 1 gene: IL9RP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 212 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,283,170–72,753,772, 1 gene, copy number 5 (within-gene range 3–5): AL513166.1.
- chr1:72,636,547–73,355,253, 8 genes, copy number 5: AL583808.1, RNU6-1246P, LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360.
- chr2:83,522,814–84,460,045, 8 genes, copy number 6–11: LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1.
- chr2:85,318,020–86,364,265, 47 genes, copy number 5–10: TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1, POLR1A, PTCD3, SNORD94, IMMT, Y_RNA, MIR4779, AC009309.1, MRPL35, REEP1, U8, AC009408.1.
- chr3:152,800,434–154,430,190, 23 genes, copy number 5–7: ATP5MGP5, P2RY1, HMGN2P13, AC117394.1, AC117394.2, RAP2B, RN7SL300P, AC078788.1, AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2.
- chr5:7,980,146–8,157,788, 4 genes, copy number 6: RNU1-76P, AC091941.1, AC091912.2, AC091912.1.
- chr5:44,495,099–45,098,647, 8 genes, copy number 5–13: LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1.
- chr11:69,414,307–71,252,577, 42 genes, copy number 16–23: AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:72,114,869–72,434,680, 17 genes, copy number 7–17: FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1.
- chr20:30,484,925–32,207,743, 54 genes, copy number 5: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2.

Autosomal genes at a single copy (total copy number 1): 14,753. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
